Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A02E, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A02E-01A (Primary Tumor).

TCGA #:

Internal Sample ID:

Diagnosis:

This is an invasive adenocarcinoma in the region of the liver.
This finding is certainly compatible with a metastasis from adenocarcinoma of the colon.

Diagnosis:

This is a moderately differentiated adenocarcinoma of the colon (G2) with infiltration of all parietal layers (pT3), with lymph vessel and blood vessel invasion (L1, V1) and with four sections of lymph node metastases (pN1), and also - in relation to the ligature and resection margins - free resection margins.

Tumor classification:

ICDO-DA-M 8140/3

G2

pT3, L1, V1, pN1, MX

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: Cecum (pw CACF) C18.0 pw 3/30/11

Dual/Syncronous Primary Noted		

Handwritten signature: *[Signature]*

Source: NCI Genomic Data Commons file b7776d6f-67c6-4a3e-98ba-47e3a0aab795 (TCGA-AA-A02E.72783514-8591-469B-B5CE-B63E274A521C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).